Somatic mutation profile of tumor specimen 0DIY6B from CCDI case PBBWEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.3 years (5,957 days).
Specimen 0DIY6B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf919f38-0cc0-426c-82b1-1fb417abad57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY60 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67a89389-0c61-48ae-920c-1ceaece64878

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MGAT4D | c.426A>T p.R142S | Missense Mutation (SNP) | VAF 56/1373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1356548403; called by muse, mutect2
- GRM5 | c.2977C>A p.P993T (on ENST00000305447 / NM_001143831.2; = p.P961T on NM_000842.4) | Missense Mutation (SNP) | VAF 67/634 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZDHHC7 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 253/2620 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PLEC | c.8292C>T p.P2764= (on ENST00000322810 / NM_201380.4; = p.P2654= on NM_000445.5) | Silent (SNP) | VAF 88/934 reads (9%) | catalogued as rs1554687742; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 78/1252 reads (6%) | called by muse, mutect2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 38/352 reads (11%) | catalogued as rs1415560984; called by mutect2, varscan2
